Somatic mutation profile of tumor specimen TCGA-FG-5965-02A (aliquot TCGA-FG-5965-02A-11D-A29Q-08) from TCGA case TCGA-FG-5965, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 39.0 years (14,249 days).
Specimen TCGA-FG-5965-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b068a963-9d1d-4df4-923d-dfc8477d7bb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-5965-10A (Blood Derived Normal), aliquot TCGA-FG-5965-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b50ea0b-26af-40aa-b74f-20abb4b65334

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 14, Splice Site 2, Nonsense Mutation 2, 3'Flank 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 34/45 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV51997783, COSV99518172; called by muse, mutect2, varscan2
- ADGRE3 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV53729639; called by muse, mutect2, varscan2
- ANO2 | c.2378C>A p.T793N (on ENST00000356134 / NM_001278597.3; = p.T797N on NM_001278596.3) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV59015876; called by muse, mutect2, varscan2
- ATRX | c.4838T>A p.L1613* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV64874373, COSV64883894; called by muse, mutect2, varscan2
- BVES | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375067894, COSV100115092, COSV58947214; called by muse, mutect2, varscan2
- CAMTA1 | c.1101C>G p.N367K | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); catalogued as COSV57892728; called by muse, mutect2, varscan2
- CCKAR | c.374T>A p.V125E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810418; called by muse, mutect2, varscan2
- CDH1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55728659; called by muse, mutect2, varscan2
- CPS1 | c.3927+2T>A p.X1309_splice | Splice Site (SNP) | VAF 23/71 reads (32%) | catalogued as COSV51806538; called by muse, mutect2, varscan2
- EYA3 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.707); catalogued as rs755186429, COSV65816241; called by muse, mutect2, varscan2
- FEZ1 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | catalogued as rs780307067, COSV99630913; called by muse, mutect2, varscan2
- HYDIN | c.10901A>C p.E3634A | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV101157799; called by mutect2, varscan2
- KANK2 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as rs147297854; called by muse, mutect2, varscan2
- LPL | c.642A>C p.R214S | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60930776; called by muse, mutect2, varscan2
- MED15 | c.1873G>A p.V625I (on ENST00000263205 / NM_001003891.3; = p.V585I on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as rs1018320157, COSV53028325; called by muse, mutect2, varscan2
- MS4A1 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.883); catalogued as rs1565194450, COSV61941950; called by muse, mutect2, varscan2
- OR5W2 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs754041941, COSV60616626; called by muse, mutect2, varscan2
- SHC1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as COSV58316094; called by muse, mutect2, varscan2
- TKTL1 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 68/391 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99474068; called by muse, mutect2, varscan2
- VPS13B | c.3271A>G p.I1091V | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.952); catalogued as rs780930460, COSV62138195; called by muse, mutect2, varscan2
- XIAP | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV63022067; called by muse, mutect2, varscan2
- AACS | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ARID2 | c.3488_3495dup p.G1166Ffs*10 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | called by mutect2, varscan2
- COL14A1 | c.4660-4_4660-2del p.X1554_splice | Splice Site (DEL) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- GNL3L | c.181A>C p.K61Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HTR3A | c.1143G>T p.M381I | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MAJIN | c.201_206del p.E68_H69del | In Frame Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- NDFIP2 | c.578A>T p.K193I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NIBAN1 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- NOP53 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PPP1R10 | c.157del p.I53Ffs*27 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- PRMT6 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACBD5 | c.279T>G p.P93= (on ENST00000375888 / NM_001352568.1; = p.P95= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV101022473; called by muse, mutect2, varscan2
- ADAM20 | c.30C>T p.I10= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV56454588; called by muse, mutect2, varscan2
- ATP4A | c.861G>A p.G287= | Silent (SNP) | VAF 53/128 reads (41%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.861G>A p.S287= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs771844125, COSV56559907; called by muse, mutect2, varscan2
- CLCN1 | c.2745G>A p.G915= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV100578300; called by muse, mutect2, varscan2
- HS3ST4 | c.852T>A p.I284= | Silent (SNP) | VAF 64/184 reads (35%) | catalogued as COSV58809397; called by muse, mutect2, varscan2
- KCNH4 | c.1749G>A p.L583= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV52917437, COSV99237613; called by muse, mutect2, varscan2
- LATS2 | c.483G>A p.G161= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV101231633; called by muse, mutect2, varscan2
- MTO1 | c.774G>A p.P258= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs748667460, COSV64773428; called by muse, mutect2, varscan2
- OR2F1 | c.279A>T p.P93= | Silent (SNP) | VAF 71/250 reads (28%) | catalogued as rs779918144, COSV101231318; called by muse, mutect2, varscan2
- OSTF1 | c.477T>G p.L159= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV60547069; called by muse, mutect2, varscan2
- PIBF1 | c.1785A>G p.L595= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV58321947; called by muse, mutect2, varscan2
- RPS6KA6 | c.333T>C p.S111= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV53118339; called by muse, mutect2
- ZNF254 | c.1068C>G p.G356= | Silent (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- FAM153CP | chr5:178056118 G>A | 3'Flank (SNP) | VAF 18/49 reads (37%) | catalogued as rs1047231505; called by muse, mutect2, varscan2
